MMRF case MMRF_1512 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/49b27462-f7bb-4cb6-940c-0158cf319c52

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.8 years (22,572 days); ISS stage: II; Days to last known disease status: 1,287 days (3.5 years); Days to last follow up: 1,287 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 158 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 162 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 160 days; Days to treatment end: 160 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 344 days; Days to treatment end: 943 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 1): M Protein 1.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 657 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.572 mg/dL; Immunoglobulin G 4.36 g/L; Immunoglobulin A 29.3 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.75 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 105 µmol/L; Calcium 2.39 mmol/L; Albumin 33 g/L; Total Protein 8.4 g/dL; C-Reactive Protein 0.1 mg/dL.
- Day 83 (ECOG 1): M Protein 1.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 73.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.131 mg/dL; Immunoglobulin G 4.48 g/L; Immunoglobulin A 5.51 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 296 ×10⁹/L; Creatinine 88 µmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 4.9 mmol/L.
- Day 180 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 69.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 5.92 g/L; Immunoglobulin A 4.28 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.99 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 90 µmol/L; Blood Urea Nitrogen 2.2 mmol/L; Calcium 2.01 mmol/L; Albumin 24 g/L; Total Protein 6.5 g/dL; Glucose 5.6 mmol/L.
- Day 257 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 6.84 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 86 µmol/L; Blood Urea Nitrogen 2.2 mmol/L; Albumin 44.3 g/L; Total Protein 6.7 g/dL; Glucose 5.7 mmol/L.
- Day 351 (ECOG 1): M Protein 4.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.71 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 105 µmol/L; Calcium 2.39 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 6 mmol/L.
- Day 435 (ECOG 1): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 4.5 mmol/L.
- Day 552 (ECOG 1): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 90 µmol/L; Calcium 1.97 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 4.5 mmol/L.
- Day 636 (ECOG 1): M Protein 4.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.56 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 148 µmol/L; Blood Urea Nitrogen 4.6 mmol/L; Calcium 2.26 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 5 mmol/L.
- Day 713 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 167 µmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 7.1 g/dL.
- Day 818 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 10.3 mmol/L; Calcium 2.24 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 5 mmol/L.
- Day 908 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.65 mg/dL; Immunoglobulin G 17.4 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 151 µmol/L; Blood Urea Nitrogen 9 mmol/L; Calcium 2.19 mmol/L; Albumin 35 g/L; Total Protein 8 g/dL; Glucose 6 mmol/L.
- Day 986 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 9.1 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 6 mmol/L.
- Day 1,084 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.988 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.7 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL.
- Day 1,210 (ECOG 1): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.873 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 8.3 mmol/L; Calcium 2.49 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 6 mmol/L.
- Day 1,287 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 106 µmol/L; Albumin 41.9 g/L; Total Protein 7 g/dL.

Other clinical attributes
- Day -1: Weight: 49 kg; Height: 156 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Multiple Myeloma.

Biospecimens (2 samples)
- Sample MMRF_1512_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1512_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
